Somatic mutation profile of tumor specimen TCGA-BB-A6UO-01A (aliquot TCGA-BB-A6UO-01A-12D-A34J-08) from TCGA case TCGA-BB-A6UO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.6 years (22,506 days).
Specimen TCGA-BB-A6UO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ecc51ac-2877-4adc-82b2-0716df56628f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-A6UO-10A (Blood Derived Normal), aliquot TCGA-BB-A6UO-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/872074d2-ebd9-4937-9ce0-5434f43ba936

The open-access MAF lists 116 somatic variants for this specimen: 85 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 29, Splice Site 5, Nonsense Mutation 5, Frame Shift Ins 4, Frame Shift Del 4, Splice Region 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+2T>G p.X307_splice | Splice Site (SNP) | VAF 46/76 reads (61%) | hotspot (GDC flag); catalogued as rs1131691016, COSV52698436, COSV52737448, COSV52774697; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.3866A>T p.D1289V | Missense Mutation (SNP) | VAF 102/330 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1170728153, COSV100711392; called by muse, mutect2, varscan2
- ADAT3 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs756591965, COSV60190047; called by muse, varscan2
- ATP10B | c.2321C>A p.S774Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100515392; called by muse, mutect2, varscan2
- BTBD10 | c.89A>G p.Y30C | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99533768; called by muse, mutect2, varscan2
- CCNI | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1476371440, COSV99423568; called by muse, mutect2, varscan2
- CES5A | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs147903375; called by muse, mutect2, varscan2
- CLSTN1 | c.2893A>T p.N965Y (on ENST00000377298 / NM_001009566.3; = p.N955Y on NM_014944.4) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100740333; called by muse, mutect2, varscan2
- CSMD3 | c.10651C>T p.R3551C (on ENST00000297405 / NM_001363185.1; = p.R3382C on NM_052900.3) | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747094531, COSV52118225, COSV99830646, COSV99853569; called by muse, mutect2, varscan2
- CSMD3 | c.5710T>A p.C1904S (on ENST00000297405 / NM_001363185.1; = p.C1800S on NM_052900.3) | Missense Mutation (SNP) | VAF 91/184 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV99840817; called by muse, mutect2, varscan2
- CSNK1E | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100725058; called by muse, mutect2, varscan2
- DDX27 | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100874737; called by muse, mutect2, varscan2
- DLGAP4 | c.2045C>T p.P682L (on ENST00000339266 / NM_001365621.1; = p.P143L on NM_183006.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100211453; called by muse, mutect2, varscan2
- DNALI1 | c.646G>A p.A216T (on ENST00000296218; = p.A194T on NM_003462.5) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs372067106; called by muse, mutect2, varscan2
- DVL1 | c.1975G>A p.G659R (on ENST00000378888 / NM_001330311.2; = p.G634R on NM_004421.3) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775980552, COSV100229690; called by muse, varscan2
- DYNC1I1 | c.423T>C p.L141= | Splice Region (SNP) | VAF 68/220 reads (31%) | catalogued as rs1361679659, COSV100268815; called by muse, mutect2, varscan2
- EDNRB | c.730G>T p.D244Y (on ENST00000377211 / NM_001201397.1; = p.D154Y on NM_000115.5) | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV100526855; called by muse, mutect2, varscan2
- EIF2AK4 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99775063; called by muse, mutect2, varscan2
- EP300 | c.3332A>G p.Y1111C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173758442, COSV99609267; called by muse, mutect2, varscan2
- EPHB3 | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs376314906; called by muse, mutect2, varscan2
- FIGN | c.603G>C p.Q201H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100292659; called by muse, mutect2, varscan2
- GAK | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.464); catalogued as rs749064090, COSV100033182, COSV58508614; called by muse, mutect2, varscan2
- GLYATL2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.048); catalogued as COSV99780454; called by muse, mutect2, varscan2
- GPAM | c.1481A>G p.Y494C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1224542990, COSV100788322; called by muse, mutect2, varscan2
- HDAC11 | c.649+1G>A p.X217_splice | Splice Site (SNP) | VAF 45/96 reads (47%) | catalogued as rs772870373, COSV99849990; called by muse, mutect2, varscan2
- HPRT1 | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100053265; called by muse, mutect2, varscan2
- HRH3 | c.99G>T p.W33C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.334); catalogued as COSV100420661, COSV104397163; called by muse, mutect2, varscan2
- HSPA4 | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs377082440; called by muse, mutect2, varscan2
- HSPG2 | c.4592G>A p.R1531H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as rs553872815, COSV101020903; called by muse, mutect2, varscan2
- HUWE1 | c.13015C>T p.H4339Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53340328, COSV99471361, COSV99473277; called by muse, mutect2, varscan2
- IFNA16 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 119/236 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV101207076; called by muse, mutect2, varscan2
- IL1RAP | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as COSV50768821; called by muse, mutect2, varscan2
- IRGQ | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs1291329028, COSV100338216; called by muse, mutect2, varscan2
- ITSN2 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.059); catalogued as rs1179551780, COSV100743894; called by muse, mutect2, varscan2
- KIAA1549 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs369822469; called by muse, mutect2, varscan2
- KIF27 | c.1612A>G p.I538V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV99927144; called by muse, mutect2, varscan2
- KIF3C | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99267656; called by muse, mutect2, varscan2
- LCN8 | c.383G>A p.R128H (on ENST00000612714 / NM_001345934.1; = p.R105H on NM_178469.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138766179; called by muse, mutect2, varscan2
- LRP12 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs777398485, COSV52633496; called by muse, mutect2, varscan2
- LYZL2 | c.326C>T p.T109M (on ENST00000375318; = p.T63M on NM_183058.3) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as rs146282381, COSV100940619; called by muse, mutect2, varscan2
- MORC1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as rs374215295; called by muse, mutect2, varscan2
- MTMR8 | c.1004T>A p.L335* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100878486; called by muse, mutect2, varscan2
- NCOA4 | c.166A>G p.I56V | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs782728572; called by muse, mutect2, varscan2
- NEUROD6 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99774123; called by muse, mutect2, varscan2
- NIPBL | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs781150294, COSV99241649; called by muse, mutect2, varscan2
- NLRP6 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs758722139, COSV100381068, COSV56458030, COSV56459262; called by muse, mutect2, varscan2
- NUP155 | c.1727A>G p.Y576C (on ENST00000231498 / NM_153485.3; = p.Y517C on NM_004298.4) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748082598, COSV99193877; called by muse, mutect2, varscan2
- OPRK1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs370616732; called by muse, mutect2, varscan2
- PCDHGC3 | c.104A>T p.Y35F | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99341326; called by muse, mutect2, varscan2
- PKNOX2 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV100021377; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1136C>A p.S379Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV51931836, COSV99240630; called by muse, mutect2, varscan2
- RBM27 | c.3050A>T p.K1017M | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99506402; called by muse, mutect2, varscan2
- RC3H2 | c.1001T>C p.L334S | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100106771; called by muse, mutect2, varscan2
- RHOT2 | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1447067503, COSV99553813; called by muse, varscan2
- RHOT2 | c.869+1G>A p.X290_splice | Splice Site (SNP) | VAF 10/84 reads (12%) | catalogued as rs1286646181, COSV99553815; called by muse, varscan2
- RNF111 | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs748327805, COSV100789113; called by muse, mutect2, varscan2
- RPL5 | c.517A>G p.I173V | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs754245145, CD152941, COSV100240428; called by muse, mutect2, varscan2
- SCNN1B | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV100225271, COSV100225808; called by muse, mutect2, varscan2
- SLC4A4 | c.2328C>A p.N776K (on ENST00000264485 / NM_001098484.3; = p.N732K on NM_003759.4) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99140826; called by muse, mutect2, varscan2
- SMAD4 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV61689992; called by muse, mutect2, varscan2
- TARBP1 | c.1266A>T p.L422F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.503); catalogued as COSV99241872; called by muse, mutect2, varscan2
- TATDN3 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167012776, COSV100875248; called by muse, mutect2, varscan2
- TBC1D15 | c.1553-1G>T p.X518_splice | Splice Site (SNP) | VAF 28/108 reads (26%) | catalogued as COSV100042002; called by muse, mutect2, varscan2
- TBC1D31 | c.1619A>G p.N540S | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as rs1188873216, COSV99782987; called by muse, mutect2, varscan2
- TMEM215 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV61363346; called by muse, mutect2, varscan2
- TNFRSF19 | c.582G>C p.K194N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99947549; called by muse, mutect2, varscan2
- TRIM46 | c.1583C>A p.A528E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100583982; called by muse, mutect2, varscan2
- UACA | c.3436C>T p.Q1146* | Nonsense Mutation (SNP) | VAF 10/264 reads (4%) | catalogued as COSV100537608; called by muse, mutect2
- UBE4B | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99477249; called by muse, mutect2
- UBN2 | c.665A>G p.Y222C | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99944224; called by muse, mutect2, varscan2
- USP36 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV100361657; called by muse, mutect2, varscan2
- VPS13B | c.3194A>T p.K1065M | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100662707; called by muse, mutect2, varscan2
- XPNPEP1 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100451063; called by muse, mutect2, varscan2
- YLPM1 | c.5713A>G p.M1905V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV99460529; called by muse, mutect2, varscan2
- ZNF646 | c.3905G>C p.G1302A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV99762502; called by muse, mutect2, varscan2
- ZNF835 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs1264888746, COSV101606382; called by muse, mutect2, varscan2
- COX11 | c.475_476dup p.A160Mfs*37 | Frame Shift Ins (INS) | VAF 31/136 reads (23%) | called by mutect2, pindel, varscan2
- DNAJC14 | c.242dup p.G82Rfs*4 | Frame Shift Ins (INS) | VAF 67/266 reads (25%) | called by mutect2, pindel, varscan2
- DYNC1I2 | c.378dup p.S127Lfs*11 | Frame Shift Ins (INS) | VAF 41/175 reads (23%) | called by mutect2, pindel, varscan2
- FBXW7 | c.398_416del p.R133Ifs*30 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- HNRNPH1 | c.520_524del p.E174Nfs*7 | Frame Shift Del (DEL) | VAF 74/307 reads (24%) | called by mutect2, pindel, varscan2
- KATNA1 | c.596_597del p.I199Nfs*11 | Frame Shift Del (DEL) | VAF 30/142 reads (21%) | called by pindel, varscan2
- KIF4A | c.488del p.I163Nfs*9 | Frame Shift Del (DEL) | VAF 22/95 reads (23%) | called by mutect2, pindel, varscan2
- NF2 | c.446_447+25del p.X149_splice | Splice Site (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel
- ZFP36L2 | c.478dup p.R160Pfs*314 | Frame Shift Ins (INS) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- C1GALT1C1 | c.27G>A p.L9= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as COSV100485631; called by muse, mutect2, varscan2
- CACNA1A | c.957G>C p.G319= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100802868; called by muse, mutect2, varscan2
- CNGA4 | c.399C>T p.G133= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as COSV101171832; called by muse, mutect2, varscan2
- COCH | c.1668T>C p.D556= (on ENST00000216361 / NM_001347720.1; = p.D491= on NM_004086.3) | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV99363776; called by muse, mutect2, varscan2
- CPNE4 | c.465C>T p.D155= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as rs754468816, COSV101456770; called by muse, mutect2, varscan2
- ELMO3 | c.2031T>C p.Y677= (on ENST00000652269; = p.Y624= on NM_024712.5) | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs888338326, COSV100440915; called by muse, mutect2, varscan2
- EYA1 | c.315T>G p.T105= | Silent (SNP) | VAF 44/161 reads (27%) | catalogued as COSV100379885; called by muse, mutect2, varscan2
- FBN3 | c.1062C>T p.P354= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs747633522, COSV99561363, COSV99561412; called by muse, mutect2, varscan2
- GRM1 | c.1557G>A p.V519= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99267619; called by muse, mutect2, varscan2
- HLA-C | c.717G>T p.L239= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100880719; called by muse, mutect2
- HYDIN | c.5757G>A p.A1919= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs764538189, COSV59249372; called by muse, mutect2, varscan2
- IHH | c.13C>A p.R5= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV99838739; called by muse, mutect2, varscan2
- KCNA7 | c.303G>A p.A101= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV99671973; called by muse, mutect2, varscan2
- LRRIQ3 | c.1428A>G p.K476= | Silent (SNP) | VAF 36/185 reads (19%) | catalogued as COSV100599038; called by muse, mutect2, varscan2
- MLLT6 | c.330C>T p.Y110= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs780174315; called by muse, mutect2, varscan2
- MUC5B | c.13290G>A p.T4430= | Silent (SNP) | VAF 137/311 reads (44%) | catalogued as rs766901971, COSV71594480; called by muse, mutect2, varscan2
- MYORG | c.1290C>T p.G430= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs945957817, COSV99898751; called by muse, mutect2, varscan2
- NFE2L2 | c.1362C>T p.L454= | Silent (SNP) | VAF 77/267 reads (29%) | catalogued as COSV101229407; called by muse, mutect2, varscan2
- NUP58 | c.159A>C p.P53= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as COSV101098843; called by muse, mutect2, varscan2
- PLEKHO1 | c.216G>C p.L72= | Silent (SNP) | VAF 53/191 reads (28%) | catalogued as COSV50310034; called by muse, mutect2, varscan2
- POU6F2 | c.1413G>A p.T471= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs371316682; called by muse, mutect2
- PRICKLE2 | c.1038A>G p.K346= (on ENST00000295902; = p.K290= on NM_198859.4) | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV99897755; called by muse, mutect2, varscan2
- SCAF1 | c.3357G>A p.A1119= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs767686210, COSV100862229; called by muse, mutect2, varscan2
- SYDE1 | c.324C>T p.G108= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs377224290, COSV100720688; called by muse, mutect2
- TMEM79 | c.489G>T p.R163= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99828016; called by muse, mutect2, varscan2
- TP53I3 | c.300T>A p.T100= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99475476; called by mutect2, varscan2
- UBR4 | c.9468T>C p.Y3156= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs765580173, COSV100921347; called by muse, mutect2, varscan2
- XIAP | c.84T>C p.N28= | Silent (SNP) | VAF 57/237 reads (24%) | catalogued as COSV100848917; called by muse, mutect2, varscan2
- ZFHX3 | c.3102C>T p.I1034= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs150708280; called by muse, mutect2, varscan2
- LINC01559 | n.354G>A | RNA (SNP) | VAF 21/63 reads (33%) | called by muse, varscan2
- METTL16 | chr17:2415262 T>A | 3'Flank (SNP) | VAF 109/174 reads (63%) | called by muse, mutect2, varscan2
